Somatic mutation profile of tumor specimen HTMCP-03-06-02386-01C (aliquot HTMCP-03-06-02386-01C-01D-10409) from CGCI case HTMCP-03-06-02386, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02386-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c80ed9f-609d-4625-9be2-f8b7d3a982b2.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02386-10A (Blood Derived Normal), aliquot HTMCP-03-06-02386-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa1cc155-99e8-4374-b4e1-2907ac86b40c

The open-access MAF lists 62 somatic variants for this specimen: 45 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 15, Nonsense Mutation 4, 3'UTR 1, Frame Shift Del 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57246789; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 46/144 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF2 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs1555993345, CM950856, COSV58519797; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TTN | c.6959G>A p.R2320H (on ENST00000591111; = p.R2274H on NM_003319.4) | Missense Mutation (SNP) | VAF 17/248 reads (7%) | PolyPhen probably damaging (0.998); catalogued as rs374615369; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- ATP1A3 | c.1948C>T p.R650W (on ENST00000545399 / NM_001256214.2; = p.R637W on NM_152296.5) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1273337984, COSV57487988; called by muse, mutect2, varscan2
- AVPR1A | c.532A>T p.S178C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.722); catalogued as COSV100146823; called by muse, mutect2, varscan2
- BCAS3 | c.2420G>A p.R807H (on ENST00000390652 / NM_001353144.2; = p.R792H on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as rs754370008, COSV66778270; called by muse, mutect2, varscan2
- BIRC6 | c.12653G>A p.R4218H | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs775201281, COSV70208748; called by muse, mutect2, varscan2
- CACNA1F | c.3056T>C p.V1019A | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59906422; called by muse, mutect2, varscan2
- CACNA1H | c.5455C>T p.R1819C | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1207672675, COSV52356469; called by muse, mutect2, varscan2
- COBL | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771778534, COSV54358837; called by muse, mutect2, varscan2
- EIF4G1 | c.1237G>A p.V413M (on ENST00000346169 / NM_198241.3; = p.V217M on NM_004953.5) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.332); catalogued as rs897000899; called by muse, mutect2, varscan2
- EPAS1 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780349023, COSV99763760; called by muse, mutect2, varscan2
- FNDC1 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV51931046; called by muse, mutect2, varscan2
- IGF1R | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV51274328; called by muse, mutect2
- KCNF1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs1179631211; called by muse, mutect2, varscan2
- LRP2 | c.4498A>T p.R1500* | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | catalogued as COSV55579530; called by muse, mutect2, varscan2
- MAGEC3 | c.77G>T p.C26F | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV53577096, COSV74217477; called by muse, mutect2, varscan2
- MYH7B | c.2956G>A p.A986T | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs767995788; called by muse, mutect2, varscan2
- NLRP8 | c.2497G>T p.A833S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.418); catalogued as rs1269673676; called by mutect2, varscan2
- PAPOLB | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1562454376, COSV68201462; called by muse, mutect2, varscan2
- PCDHA13 | c.1026T>A p.D342E | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs782475623; called by muse, mutect2, varscan2
- PIEZO2 | c.113T>A p.L38H | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57453498; called by muse, mutect2, varscan2
- SPEN | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 15/133 reads (11%) | catalogued as COSV65357510; called by muse, mutect2, varscan2
- TMEM132D | c.3157G>A p.V1053I | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750913130, COSV67160883; called by muse, mutect2, varscan2
- TMEM132D | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs200646338, COSV101398364, COSV70598520; called by muse, mutect2, varscan2
- TTN | c.68380C>T p.R22794C (on ENST00000591111; = p.R15370C on NM_003319.4) | Missense Mutation (SNP) | VAF 41/130 reads (32%) | PolyPhen probably damaging (0.998); catalogued as rs200028088; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF292 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 23/285 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs762030565, COSV60545630; called by muse, mutect2
- ADGRV1 | c.4523A>G p.H1508R | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CHD4 | c.2878A>G p.I960V (on ENST00000357008 / NM_001363606.2; = p.I973V on NM_001273.5) | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- COCH | c.1120C>A p.L374M (on ENST00000216361 / NM_001347720.1; = p.L309M on NM_004086.3) | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- CSMD1 | c.8390G>C p.C2797S (on ENST00000520002; = p.C2796S on NM_033225.6) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- FRMD8 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); called by muse, varscan2
- ITGAX | c.3174+1G>A p.X1058_splice | Splice Site (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- KMT2C | c.2835_2836del p.L946Vfs*3 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by pindel, varscan2
- LIMA1 | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PBRM1 | c.2099T>C p.I700T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDE1C | c.1448T>A p.V483D | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.216); called by muse, mutect2
- PHKA2 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- PNPLA6 | c.1826A>G p.K609R (on ENST00000414982 / NM_001166111.2; = p.K561R on NM_006702.5) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- RSF1 | c.4280G>C p.R1427T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- SETD1A | c.1279C>G p.P427A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TRIM33 | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | called by muse, mutect2, varscan2
- ZGRF1 | c.5374G>A p.A1792T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARHGAP4 | c.1308C>T p.T436= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs782223874; called by muse, mutect2, varscan2
- FAM135B | c.3660C>T p.G1220= | Silent (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- FREM2 | c.6408A>T p.I2136= | Silent (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- MSTO1 | c.1128C>T p.F376= | Silent (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2, varscan2
- NAF1 | c.420G>A p.S140= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs1263975601; called by muse, mutect2, varscan2
- NFATC3 | c.1545T>C p.I515= | Silent (SNP) | VAF 14/116 reads (12%) | called by mutect2, varscan2
- PIK3CG | c.2652C>T p.D884= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs755002463, COSV63248548; called by muse, mutect2, varscan2
- PRUNE2 | c.6327C>T p.H2109= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs368601913; called by muse, mutect2, varscan2
- RNF111 | c.1965G>A p.R655= | Silent (SNP) | VAF 61/187 reads (33%) | called by muse, mutect2, varscan2
- ROR2 | c.2274G>A p.S758= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs139915017; called by muse, varscan2
- SCN1A | c.4320A>G p.A1440= (on ENST00000303395 / NM_001202435.3; = p.A1429= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/128 reads (26%) | called by muse, mutect2, varscan2
- SHROOM4 | c.702T>A p.A234= | Silent (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.3261C>T p.P1087= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs746455853; called by muse, mutect2, varscan2
- SKIDA1 | c.2673C>T p.G891= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as COSV71610903, COSV71611106; called by muse, mutect2
- ZFYVE26 | c.5145C>T p.D1715= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as rs371086321; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSSC2 | chr11:3413937 C>T | 3'Flank (SNP) | VAF 39/98 reads (40%) | called by muse, mutect2, varscan2
- XIRP2 | c.*604A>G | 3'UTR (SNP) | VAF 19/150 reads (13%) | catalogued as COSV54685789; called by muse, mutect2, varscan2
